Gene-level copy-number profile of tumor specimen HTMCP-03-06-02203-01A from CGCI case HTMCP-03-06-02203, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.4 years (23,873 days).
Specimen HTMCP-03-06-02203-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 010ae6cd-aa44-442d-8fc0-b4dfba7513cb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02203-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ad249062-cec9-4070-a662-c5234b31e22c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,508; copy number 2: 16,332; copy number 3: 25,071; copy number 4: 6,187; copy number 5: 3,832; copy number 6: 2,757; copy number 7: 178; copy number 8: 99; copy number 9: 34; copy number 10: 113; copy number 11: 77; copy number 12: 138; copy number 13: 51; copy number 14: 8; copy number 15: 12; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,866,658–6,880,626, 2 genes: OR7E136P, OR7E59P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 711 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:154,007,367–154,861,017, 14 genes, copy number 7: U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15, AC073359.2.
- chr3:156,539,553–158,106,420, 29 genes, copy number 7 (within-gene range 6–7): SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1, PTX3, SLC66A1L, AC084212.1, AC079943.2, RN7SKP46, AC079943.1, SHOX2.
- chr3:161,083,883–161,503,942, 10 genes, copy number 8: B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1.
- chr3:163,026,396–184,027,756, 299 genes, copy number 7–17 (broad region; genes not listed).
- chr3:197,298,252–197,627,906, 8 genes, copy number 8 (within-gene range 4–8): DLG1-AS1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1.
- chr3:197,660,565–198,123,232, 21 genes, copy number 8: AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:58,198–58,915, 1 gene, copy number 10: AC113430.1.
- chr11:128,614,340–131,350,917, 50 genes, copy number 7–9: AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2, MIR8052, LINC02873, PPP1R10P1, LINC02551, SNX19, AP003486.1, RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr13:114,281,601–114,337,626, 4 genes, copy number 8: UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:21,148,370–21,511,342, 17 genes, copy number 7: OR5AU1, SMARCE1P3, AL157687.1, LINC00641, HNRNPC, RPGRIP1, SUPT16H, AL135744.1, CHD8, SNORD9, SNORD8, AL161747.1, EIF4EBP1P1, RN7SL650P, RAB2B, TOX4, METTL3.
- chr14:21,887,857–22,487,245, 65 genes, copy number 10–12 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 12: TRAC.
- chr14:24,318,349–26,143,305, 25 genes, copy number 7: ADCY4, AL096870.1, RIPK3, NFATC4, NYNRIN, CBLN3, KHNYN, SDR39U1, AL132800.1, CMA1, CTSG, AL136018.1, GZMH, GZMB, STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1.
- chr14:30,437,992–38,041,442, 144 genes, copy number 8–14 (within-gene range 3–14) (broad region; genes not listed).
- chr15:59,768,352–61,229,302, 23 genes, copy number 7 (within-gene range 3–7): RPS3AP6, AC092079.1, NMNAT1P5, FOXB1, MESTP2, AC009654.1, ANXA2, AC087385.1, AC087385.2, AC087385.3, ICE2, RORA-AS1, RORA, AC107241.1, CYCSP38, AC009560.1, AC009560.3, AC009560.4, AC009560.2, RORA-AS2, RNA5SP397, AC022898.1, AC022898.2.

Autosomal genes at a single copy (total copy number 1): 2,652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
